Somatic mutation profile of tumor specimen TCGA-13-0924-01A (aliquot TCGA-13-0924-01A-01W-0421-09) from TCGA case TCGA-13-0924, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 45.6 years (16,670 days).
Specimen TCGA-13-0924-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 43d1bc37-17f6-4726-8b3f-644aafee2add.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0924-10A (Blood Derived Normal), aliquot TCGA-13-0924-10A-01W-0421-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56a41936-a1ac-4535-9896-c1521a8db3b9

The open-access MAF lists 79 somatic variants for this specimen: 67 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 53, Silent 12, Nonsense Mutation 7, Frame Shift Ins 2, Frame Shift Del 2, Splice Site 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.810T>G p.F270L | Missense Mutation (SNP) | VAF 28/72 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1057519987, COSV52809003, COSV53009334; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- WDR35 | c.1415G>A p.R472Q (on ENST00000345530 / NM_001006657.2; = p.R461Q on NM_020779.4) | Missense Mutation (SNP) | VAF 102/434 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.107); catalogued as rs200140363, COSV55601925, COSV99852911; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAM12 | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 155/365 reads (42%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV64102839; called by muse, mutect2, varscan2
- AHNAK | c.8106C>G p.I2702M | Missense Mutation (SNP) | VAF 109/502 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.413); catalogued as COSV57234086; called by muse, mutect2, varscan2
- APOB | c.10881G>C p.K3627N | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV51956137; called by muse, mutect2, varscan2
- ARHGEF11 | c.3928G>A p.D1310N | Missense Mutation (SNP) | VAF 51/196 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as rs753788298, COSV59359296; called by muse, mutect2, varscan2
- C10orf90 | c.1992G>T p.K664N | Missense Mutation (SNP) | VAF 35/238 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1016007416, COSV52963383; called by muse, mutect2, varscan2
- CACNA2D1 | c.2297G>C p.R766T (on ENST00000356253 / NM_001366867.1; = p.R754T on NM_000722.4) | Missense Mutation (SNP) | VAF 51/184 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as COSV62394939; called by muse, mutect2, varscan2
- CASK | c.1240G>T p.E414* | Nonsense Mutation (SNP) | VAF 22/54 reads (41%) | catalogued as COSV59376936; called by muse, mutect2, varscan2
- CASP5 | c.567G>C p.E189D | Missense Mutation (SNP) | VAF 61/214 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.165); catalogued as COSV52828304, COSV52832542; called by muse, mutect2, varscan2
- CBLN4 | c.151G>T p.D51Y | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV50354615; called by muse, mutect2
- CCDC148 | c.901T>A p.L301M | Missense Mutation (SNP) | VAF 144/247 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51772217; called by muse, mutect2, varscan2
- CDRT1 | c.1482C>G p.H494Q | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV63054468; called by muse, mutect2, varscan2
- CPA6 | c.764A>T p.K255I | Missense Mutation (SNP) | VAF 229/480 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52744400; called by muse, mutect2, varscan2
- CSMD1 | c.6224G>C p.G2075A (on ENST00000520002; = p.G2074A on NM_033225.6) | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267601893; called by muse, mutect2
- CSMD3 | c.6236A>G p.D2079G (on ENST00000297405 / NM_001363185.1; = p.D1975G on NM_052900.3) | Missense Mutation (SNP) | VAF 50/224 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV52342117; called by muse, mutect2
- DCLRE1C | c.650C>A p.T217N (on ENST00000378278 / NM_001350965.2; = p.T102N on NM_022487.4) | Missense Mutation (SNP) | VAF 260/927 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as COSV63185874; called by muse, mutect2, varscan2
- DIDO1 | c.1979G>A p.S660N | Missense Mutation (SNP) | VAF 70/121 reads (58%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs376360803; called by muse, mutect2, varscan2
- DNMT3A | c.1241T>C p.F414S | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1258189576, COSV53081913; called by muse, mutect2, varscan2
- DQX1 | c.1704A>T p.E568D | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.031); catalogued as COSV52047300; called by muse, mutect2, varscan2
- ESRRB | c.134T>C p.F45S | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.103); catalogued as COSV55067992; called by muse, mutect2, varscan2
- FLG | c.6053G>A p.R2018K | Missense Mutation (SNP) | VAF 154/448 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.333); catalogued as COSV64251262; called by muse, mutect2, varscan2
- FSHR | c.1896C>A p.N632K | Missense Mutation (SNP) | VAF 66/176 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as COSV58625057; called by muse, mutect2, varscan2
- GMPS | c.1876C>T p.Q626* | Nonsense Mutation (SNP) | VAF 72/208 reads (35%) | catalogued as COSV55812384; called by muse, mutect2, varscan2
- HGF | c.1558G>T p.G520* | Nonsense Mutation (SNP) | VAF 19/78 reads (24%) | catalogued as COSV55954682, COSV55958241; called by muse, mutect2, varscan2
- HPS3 | c.1967C>T p.P656L | Missense Mutation (SNP) | VAF 52/234 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1280378060, COSV56057849; called by muse, mutect2, varscan2
- KHDRBS3 | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 83/446 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.204); catalogued as COSV63424736; called by muse, mutect2, varscan2
- KLHL25 | c.1702A>G p.I568V | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61996753; called by muse, mutect2, varscan2
- LAMA3 | c.8501G>T p.G2834V (on ENST00000313654 / NM_198129.4; = p.G1225V on NM_000227.6) | Missense Mutation (SNP) | VAF 150/294 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV52544890, COSV99335305; called by mutect2, varscan2
- MGA | c.1935C>A p.S645R | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV54964563; called by muse, mutect2, varscan2
- MOG | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 47/225 reads (21%) | catalogued as rs201832372, COSV65305893; called by muse, mutect2, varscan2
- MUC16 | c.2306T>A p.V769D | Missense Mutation (SNP) | VAF 78/450 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV101200551, COSV67499866; called by muse, mutect2, varscan2
- MYH15 | c.4339G>A p.V1447I | Missense Mutation (SNP) | VAF 68/121 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as COSV56321473; called by muse, mutect2, varscan2
- NBEA | c.6656G>C p.R2219P | Missense Mutation (SNP) | VAF 55/100 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV59769775, COSV59829121; called by muse, mutect2, varscan2
- NCOA2 | c.3617T>G p.L1206R | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as COSV51224024; called by muse, mutect2, varscan2
- NIPBL | c.5069A>G p.K1690R | Missense Mutation (SNP) | VAF 47/172 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.056); catalogued as COSV56968591; called by muse, mutect2, varscan2
- OR4K2 | c.927T>A p.N309K | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV53852064; called by muse, mutect2, varscan2
- PAGE2 | c.220G>T p.E74* | Nonsense Mutation (SNP) | VAF 64/392 reads (16%) | catalogued as COSV66596265; called by muse, mutect2, varscan2
- PKHD1 | c.2623C>G p.P875A | Missense Mutation (SNP) | VAF 54/305 reads (18%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.965); catalogued as COSV61897569; called by muse, mutect2, varscan2
- PMPCB | c.845G>C p.S282T | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs765855979, COSV50788414; called by muse, mutect2, varscan2
- PRG4 | c.1555C>A p.P519T | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as rs1206341210, COSV63355516; called by muse, mutect2, varscan2
- RBM14 | c.341A>G p.Y114C | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); catalogued as COSV59561126; called by muse, mutect2, varscan2
- RBM14 | c.1824A>C p.L608F | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.047); catalogued as COSV59561137; called by muse, mutect2, varscan2
- RGS18 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201783745, COSV66507439; called by muse, mutect2, varscan2
- RNASE12 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.122); catalogued as COSV60088485; called by muse, mutect2, varscan2
- SLIT1 | c.3077A>T p.N1026I | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV56600886; called by muse, mutect2, varscan2
- SMARCAD1 | c.518G>A p.S173N | Missense Mutation (SNP) | VAF 71/111 reads (64%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV62776470; called by muse, mutect2, varscan2
- TESK2 | c.328C>T p.H110Y | Missense Mutation (SNP) | VAF 105/347 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59158097; called by muse, mutect2, varscan2
- TMEM126A | c.179T>C p.V60A | Missense Mutation (SNP) | VAF 107/288 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV58736267; called by muse, mutect2, varscan2
- UNC13A | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT tolerated, low confidence (0.3); PolyPhen probably damaging (0.994); catalogued as rs762018926, COSV53213419; called by muse, mutect2, varscan2
- VCPIP1 | c.2008G>T p.G670C | Missense Mutation (SNP) | VAF 257/520 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.888); catalogued as COSV60050374; called by muse, mutect2, varscan2
- ZC3H6 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 53/85 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59671000; called by muse, mutect2, varscan2
- C10orf90 | c.1993A>T p.K665* | Nonsense Mutation (SNP) | VAF 34/243 reads (14%) | called by muse, mutect2, varscan2
- CCNE1 | c.1031C>G p.S344* | Nonsense Mutation (SNP) | VAF 8/204 reads (4%) | called by muse, mutect2
- CSMD1 | c.4847A>G p.D1616G (on ENST00000520002; = p.D1615G on NM_033225.6) | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- ECD | c.1302dup p.E435Rfs*15 | Frame Shift Ins (INS) | VAF 52/175 reads (30%) | called by mutect2, pindel, varscan2
- FUT8 | c.1429G>C p.E477Q (on ENST00000360689 / NM_001371534.1; = p.E314Q on NM_004480.4) | Missense Mutation (SNP) | VAF 16/365 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- HINFP | c.715del p.A239Pfs*14 | Frame Shift Del (DEL) | VAF 49/176 reads (28%) | called by mutect2, pindel, varscan2
- KCNJ15 | c.1093C>A p.L365M | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.697); called by muse, mutect2
- KRT71 | c.802_813+2del p.X268_splice | Splice Site (DEL) | VAF 35/167 reads (21%) | called by mutect2, pindel, varscan2
- LMBR1L | c.770-12_793del p.X257_splice | Splice Site (DEL) | VAF 24/128 reads (19%) | called by mutect2, pindel
- OSBPL3 | c.2434C>G p.P812A | Missense Mutation (SNP) | VAF 14/317 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2
- PAH | c.289_296del p.I97Afs*2 | Frame Shift Del (DEL) | VAF 83/271 reads (31%) | called by mutect2, pindel, varscan2
- PCDHA5 | c.113C>G p.A38G | Missense Mutation (SNP) | VAF 2/16 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.539); called by muse, mutect2
- SLC17A6 | c.1133_1135delinsCAACTTGTTG p.I378Tfs*34 | Frame Shift Ins (INS) | VAF 66/324 reads (20%) | called by pindel, varscan2*
- UNC79 | c.6449G>C p.C2150S (on ENST00000393151 / NM_001346218.2; = p.C1973S on NM_020818.5) | Missense Mutation (SNP) | VAF 24/433 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); called by muse, mutect2
- ZNF335 | c.2367_2384del p.M790_A795del | In Frame Del (DEL) | VAF 7/26 reads (27%) | called by mutect2, pindel, varscan2
- FASTKD3 | c.1104T>C p.P368= | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as COSV52947405; called by muse, mutect2, varscan2
- GDF2 | c.225C>G p.V75= | Silent (SNP) | VAF 17/52 reads (33%) | called by muse, varscan2
- GSDMC | c.1497C>G p.L499= | Silent (SNP) | VAF 109/519 reads (21%) | catalogued as rs1199060989, COSV52700025; called by muse, mutect2, varscan2
- IKBKE | c.1200C>T p.P400= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV65627211; called by muse, mutect2, varscan2
- MDN1 | c.2023C>T p.L675= | Silent (SNP) | VAF 16/454 reads (4%) | called by muse, mutect2
- SC5D | c.360C>T p.V120= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as rs369858836; called by muse, mutect2, varscan2
- SIGLEC6 | c.1146A>G p.Q382= | Silent (SNP) | VAF 91/288 reads (32%) | catalogued as COSV58437953; called by muse, mutect2, varscan2
- SPINK6 | c.90T>C p.C30= | Silent (SNP) | VAF 46/120 reads (38%) | catalogued as COSV57779234; called by muse, mutect2, varscan2
- SUSD6 | c.911G>A p.*304= | Silent (SNP) | VAF 34/174 reads (20%) | catalogued as COSV61367037; called by muse, mutect2, varscan2
- SVIL | c.4278C>G p.V1426= (on ENST00000355867 / NM_021738.3; = p.V1000= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV63449065; called by muse, mutect2, varscan2
- TTC25 | c.990G>A p.Q330= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV66369366; called by muse, mutect2, varscan2
- UGT3A1 | c.1365G>T p.L455= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV57104243; called by muse, mutect2
